Somatic mutation profile of cancer-model specimen HCM-BROD-0794-C16-85M (3D Organoid, passage 4; aliquot HCM-BROD-0794-C16-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0794-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 41.4 years (15,107 days).
Specimen HCM-BROD-0794-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1abc886f-c021-4eec-a6e9-06a50c43e50e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0794-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0794-C16-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f3ca8c9-05f9-4903-846e-bdd46c6cf9fb

The open-access MAF lists 235 somatic variants for this specimen: 179 protein-altering or splice-affecting, 52 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 52, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 4, Frame Shift Ins 4, In Frame Del 3, Intron 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 185/363 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 334/540 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 52/914 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as rs201194092, COSV58687865; called by muse, mutect2
- ABCC10 | c.4186C>G p.L1396V (on ENST00000372530 / NM_001198934.2; = p.L1368V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/311 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as rs761216822, COSV55088409; called by muse, mutect2, varscan2
- ADCY1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs778010377, COSV52032934; called by muse, mutect2, varscan2
- ADCY6 | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 201/432 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57167028; called by muse, mutect2, varscan2
- ADRA1D | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 293/587 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1454670834; called by muse, mutect2, varscan2
- BCL9L | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 319/634 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV52684271; called by muse, mutect2, varscan2
- BTBD9 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 179/382 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763503283, COSV100022465; called by muse, mutect2, varscan2
- CDH1 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 254/499 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55737842; called by muse, mutect2, varscan2
- CILK1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 246/501 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759923813; called by muse, mutect2, varscan2
- CNOT3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 638/1020 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV99651487; called by muse, mutect2, varscan2
- CSNK2A1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1057518092, COSV53933710, COSV99424810; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / not provided; called by muse, mutect2
- DENND3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 173/560 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs773734634, COSV52805162, COSV99370069; called by muse, mutect2, varscan2
- DLGAP2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 1163/1163 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs775453367; called by muse, mutect2, varscan2
- EPB41L2 | c.37_39del p.K13del | In Frame Del (DEL) | VAF 132/301 reads (44%) | catalogued as rs778438093; called by pindel, varscan2
- EPHA6 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 181/420 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.427); catalogued as rs368808214; called by muse, mutect2, varscan2
- ESPNL | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 212/469 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as rs570258039, COSV100547994, COSV58034956; called by muse, mutect2, varscan2
- FAM78B | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 284/596 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV100597304; called by muse, mutect2, varscan2
- FAM83A | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 381/996 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414770; called by muse, mutect2, varscan2
- FAT3 | c.4637G>A p.R1546Q | Missense Mutation (SNP) | VAF 224/449 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs746923546, COSV53086601, COSV53187272; called by muse, mutect2, varscan2
- FHDC1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 163/326 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750200704, COSV52597533; called by muse, mutect2, varscan2
- G3BP2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 369/710 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV62976140; called by muse, mutect2, varscan2
- GGTLC1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 344/667 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as rs1299966954; called by muse, mutect2, varscan2
- GGTLC1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 34/767 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1273843694; called by muse, mutect2
- GLYR1 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 201/413 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs777540400; called by muse, mutect2, varscan2
- GRIK2 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242624232; called by muse, mutect2, varscan2
- GRXCR1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 219/442 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs201948629; called by muse, mutect2, varscan2
- HIVEP3 | c.6512G>A p.R2171Q | Missense Mutation (SNP) | VAF 274/568 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs866750046, COSV56010159, COSV56015737; called by muse, mutect2, varscan2
- HPF1 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 171/332 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as rs752736220; called by muse, mutect2, varscan2
- IGDCC4 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 301/581 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567084859; called by muse, mutect2, varscan2
- ITIH6 | c.2986G>C p.A996P | Missense Mutation (SNP) | VAF 342/693 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as COSV54486154; called by muse, mutect2, varscan2
- KCNG4 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 245/503 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs145735728, COSV57584380; called by muse, mutect2, varscan2
- KHDRBS2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.164); catalogued as COSV55441329, COSV55467990, COSV55491198; called by muse, mutect2, varscan2
- KIAA1109 | c.13130-1G>T p.X4377_splice | Splice Site (SNP) | VAF 115/236 reads (49%) | catalogued as rs80073281; called by muse, mutect2, varscan2
- KIF2B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 273/518 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370597263; called by muse, mutect2, varscan2
- KIR3DL1 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 76/238 reads (32%) | catalogued as COSV58492268; called by muse, mutect2, varscan2
- KLF17 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 257/514 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64855896; called by muse, mutect2, varscan2
- LRRK2 | c.4654C>T p.R1552* | Nonsense Mutation (SNP) | VAF 184/372 reads (49%) | catalogued as rs921266719, COSV100111400; called by muse, mutect2, varscan2
- MAGEB6 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 159/341 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs201048484, COSV66872093, COSV66873453; called by muse, mutect2, varscan2
- MELTF | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs779949038; called by muse, mutect2, varscan2
- MIDEAS | c.939dup p.N314Qfs*38 | Frame Shift Ins (INS) | VAF 164/357 reads (46%) | catalogued as rs762448666; called by mutect2, varscan2
- MIDEAS | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 282/650 reads (43%) | catalogued as COSV54098459; called by muse, mutect2, varscan2
- MYH9 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 231/438 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53381778; called by muse, mutect2, varscan2
- NDST4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs202173066, COSV104387051, COSV52132150; called by muse, mutect2, varscan2
- NRXN2 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs1408932933; called by muse, mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 356/696 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, varscan2
- PAOX | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 258/516 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs1475500257; called by muse, mutect2, varscan2
- PARD3 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 238/524 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.049); catalogued as rs1310344906; called by muse, varscan2
- PCSK4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 471/891 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142181980; called by muse, mutect2, varscan2
- PDS5A | c.2686A>G p.I896V | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs767404786; called by muse, mutect2, varscan2
- PER3 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 200/447 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1186369965, COSV50012673; called by muse, mutect2, varscan2
- PIGG | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746660978, COSV56321968; called by muse, mutect2, varscan2
- PIWIL3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 166/374 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as rs201110363, COSV59995927; called by muse, mutect2, varscan2
- PLXND1 | c.5099C>T p.P1700L | Missense Mutation (SNP) | VAF 270/579 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208037803, COSV100139517, COSV100140255; called by muse, mutect2, varscan2
- PPP4R4 | c.1221C>A p.D407E | Missense Mutation (SNP) | VAF 188/399 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58551806; called by muse, mutect2, varscan2
- RALGAPA2 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 178/374 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs780580184, COSV52501004; called by muse, varscan2
- RBM39 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 132/249 reads (53%) | catalogued as COSV53614086; called by muse, mutect2, varscan2
- RP1 | c.4597G>T p.A1533S | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV55123488; called by muse, mutect2, varscan2
- RSU1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 138/281 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs200148474, COSV61709234; called by muse, mutect2, varscan2
- SAA1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 158/368 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV62946155, COSV62946538; called by muse, mutect2
- SCAF1 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 779/1138 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1314430339; called by muse, varscan2
- SCN9A | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 113/256 reads (44%) | catalogued as rs1553495110; called by muse, varscan2
- SHISA7 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 1044/1555 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs532701898, COSV66244977; called by muse, mutect2, varscan2
- SLC7A3 | c.1688C>A p.T563K | Missense Mutation (SNP) | VAF 206/469 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV53227151; called by muse, mutect2, varscan2
- SOST | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 281/590 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs574411567, COSV57013139; called by muse, mutect2, varscan2
- SOX9 | c.505dup p.H169Pfs*83 | Frame Shift Ins (INS) | VAF 265/642 reads (41%) | catalogued as COSV55426944; called by mutect2, pindel, varscan2
- SPATA22 | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1389373328; called by muse, mutect2
- SPTB | c.5680G>A p.G1894R | Missense Mutation (SNP) | VAF 321/618 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs116677071; called by muse, mutect2, varscan2
- SYNE1 | c.12845C>T p.A4282V (on ENST00000367255 / NM_182961.4; = p.A4211V on NM_033071.3) | Missense Mutation (SNP) | VAF 190/356 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV55014598; called by muse, mutect2, varscan2
- TCTN2 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs531586530; called by muse, mutect2, varscan2
- TNS3 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 122/288 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100236824; called by muse, mutect2, varscan2
- TRIM3 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 294/598 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs751113447; called by muse, mutect2, varscan2
- TRPM2 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 347/656 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as rs779734671, COSV100309213; called by muse, mutect2, varscan2
- UNC13A | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 202/443 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs777663703; called by muse, mutect2, varscan2
- VCAN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977327386, COSV54103469; called by muse, mutect2, varscan2
- ZNF48 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 268/535 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754500339; called by muse, mutect2, varscan2
- ZNF611 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 313/518 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1413110364; called by muse, mutect2, varscan2
- ZNRF3 | c.2483G>A p.R828H (on ENST00000544604 / NM_001206998.2; = p.R728H on NM_032173.3) | Missense Mutation (SNP) | VAF 373/757 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs557631529; called by muse, mutect2, varscan2
- ABAT | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 293/565 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC011462.1 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 259/796 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC242842.3 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 71/225 reads (32%) | called by muse, mutect2, varscan2
- AKAP8 | c.253T>C p.C85R | Missense Mutation (SNP) | VAF 355/674 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- APOB | c.9632dup p.N3211Kfs*14 | Frame Shift Ins (INS) | VAF 148/328 reads (45%) | called by mutect2, varscan2
- ARHGAP27 | c.2176C>A p.L726M (on ENST00000428638 / NM_001282290.1; = p.L385M on NM_199282.3) | Missense Mutation (SNP) | VAF 165/382 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF12 | c.2026dup p.S676Ffs*9 | Frame Shift Ins (INS) | VAF 129/303 reads (43%) | called by mutect2, pindel, varscan2
- ARSJ | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 174/367 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- BAHCC1 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 349/727 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BAZ2B | c.4114T>G p.L1372V | Missense Mutation (SNP) | VAF 233/432 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTBD2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BTNL8 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 229/474 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf96 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 315/638 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CCDC88A | c.2746T>G p.L916V | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CCDC88C | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 298/642 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CCNA1 | c.1246T>G p.L416V | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CD22 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 311/950 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CDC42 | c.50C>A p.T17K | Missense Mutation (SNP) | VAF 163/324 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CDCA7 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 130/287 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFAP57 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 180/348 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTLN | c.2997G>T p.Q999H | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CSMD3 | c.6919C>A p.Q2307K (on ENST00000297405 / NM_001363185.1; = p.Q2203K on NM_052900.3) | Missense Mutation (SNP) | VAF 198/390 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CTC1 | c.3429G>A p.W1143* | Nonsense Mutation (SNP) | VAF 197/387 reads (51%) | called by muse, mutect2, varscan2
- DACH2 | c.1538-1G>T p.X513_splice | Splice Site (SNP) | VAF 191/381 reads (50%) | called by muse, mutect2, varscan2
- DBF4B | c.17_19+18del p.X6_splice | Splice Site (DEL) | VAF 92/303 reads (30%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- DDX41 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 312/619 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DEPTOR | c.112_122+1del | In Frame Del (DEL) | VAF 511/549 reads (93%) | called by mutect2, pindel, varscan2
- DNAAF5 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 221/465 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH1 | c.7799C>G p.S2600W | Missense Mutation (SNP) | VAF 235/495 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FSIP2 | c.15719del p.L5240Yfs*41 | Frame Shift Del (DEL) | VAF 118/322 reads (37%) | called by mutect2, pindel, varscan2
- GABRG3 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 203/407 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATAD2B | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 300/604 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, varscan2
- GLIS1 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 453/920 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- IGHV4-39 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 122/243 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- IRS4 | c.1018T>G p.C340G | Missense Mutation (SNP) | VAF 432/862 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ITPR2 | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 419/644 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2481del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 171/438 reads (39%) | called by mutect2, pindel, varscan2
- KCNT2 | c.543+1G>T p.X181_splice | Splice Site (SNP) | VAF 97/217 reads (45%) | called by muse, mutect2, varscan2
- KIAA1109 | c.13130A>T p.D4377V | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL4 | c.819T>G p.N273K | Missense Mutation (SNP) | VAF 493/496 reads (99%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LARP6 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 265/558 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1B | c.5092C>T p.L1698F | Missense Mutation (SNP) | VAF 170/358 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGED2 | c.1520T>A p.L507H | Missense Mutation (SNP) | VAF 88/1011 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MMS22L | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 196/393 reads (50%) | called by muse, mutect2, varscan2
- MROH1 | c.2736G>C p.M912I | Missense Mutation (SNP) | VAF 211/706 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MROH9 | c.2259G>T p.K753N | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- MUSK | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 411/413 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MYF5 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 220/453 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYH9 | c.3868del p.S1290Afs*36 | Frame Shift Del (DEL) | VAF 238/604 reads (39%) | called by mutect2, pindel, varscan2
- MYH9 | c.3589G>T p.A1197S | Missense Mutation (SNP) | VAF 199/530 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MYH9 | c.3588G>T p.Q1196H | Missense Mutation (SNP) | VAF 202/535 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- NCAPD2 | c.49T>A p.L17M | Missense Mutation (SNP) | VAF 338/522 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS2 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 228/496 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NUAK1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 305/610 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OFD1 | c.796_797del p.S266Yfs*3 | Frame Shift Del (DEL) | VAF 128/398 reads (32%) | called by pindel, varscan2
- OR2T4 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 420/925 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP8 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 310/641 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH15 | c.1789T>A p.S597T | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2
- PCDH18 | c.3209G>T p.G1070V | Missense Mutation (SNP) | VAF 295/556 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PCDHGA12 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 297/606 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZD2 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 160/554 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PHEX | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 260/484 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PHLPP1 | c.5012A>G p.E1671G | Missense Mutation (SNP) | VAF 272/529 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PI16 | c.745T>G p.S249A | Missense Mutation (SNP) | VAF 279/635 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PIGA | c.848G>T p.R283M | Missense Mutation (SNP) | VAF 133/240 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIGA | c.847A>G p.R283G | Missense Mutation (SNP) | VAF 136/245 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PLK1 | c.1795del p.R599Vfs*58 | Frame Shift Del (DEL) | VAF 58/488 reads (12%) | called by mutect2, pindel, varscan2
- PODXL2 | c.265_312del p.S89_E104del | In Frame Del (DEL) | VAF 150/523 reads (29%) | called by mutect2, pindel
- POU4F1 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 326/636 reads (51%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- PRDM13 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 407/890 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PRICKLE3 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 417/871 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PROSER1 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- PTCHD4 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 276/606 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RFLNA | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 246/532 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RFTN1 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 230/528 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGL3 | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 223/428 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNF19B | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 152/303 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RTP1 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SCN3A | c.4824G>T p.E1608D | Missense Mutation (SNP) | VAF 192/357 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SENP3 | c.978_979del p.Q326Hfs*11 | Frame Shift Del (DEL) | VAF 150/388 reads (39%) | called by mutect2, pindel, varscan2
- SNX19 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SOBP | c.2495C>A p.P832Q | Missense Mutation (SNP) | VAF 307/609 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOX6 | c.2158G>A p.E720K (on ENST00000528429 / NM_001145819.2; = p.E693K on NM_017508.3) | Missense Mutation (SNP) | VAF 167/352 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SOX9 | c.911del p.P304Rfs*79 | Frame Shift Del (DEL) | VAF 328/753 reads (44%) | called by mutect2, pindel, varscan2
- SPIN4 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 290/577 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- STRC | c.5084A>C p.K1695T | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SV2B | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 222/453 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SYNM | c.3856A>T p.K1286* | Nonsense Mutation (SNP) | VAF 259/506 reads (51%) | called by muse, mutect2, varscan2
- TBC1D19 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TESPA1 | c.1386G>C p.Q462H (on ENST00000316577 / NM_001098815.3; = p.Q324H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 240/531 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TRIL | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 480/960 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TSC22D2 | c.1288T>A p.S430T | Missense Mutation (SNP) | VAF 377/721 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.31369G>C p.E10457Q (on ENST00000591111; = p.E9530Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/303 reads (45%) | PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TUBB | c.810T>A p.F270L | Missense Mutation (SNP) | VAF 397/847 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- VEPH1 | c.961C>A p.H321N | Missense Mutation (SNP) | VAF 293/553 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- XIRP2 | c.1258G>A p.D420N (on ENST00000628543; = p.D595N on NM_152381.6) | Missense Mutation (SNP) | VAF 198/396 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZFP28 | c.1455C>A p.F485L | Missense Mutation (SNP) | VAF 188/591 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF611 | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 310/518 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF667 | c.1210C>A p.H404N | Missense Mutation (SNP) | VAF 181/594 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AARS1 | c.2436G>A p.K812= | Silent (SNP) | VAF 206/407 reads (51%) | catalogued as rs780744801; called by muse, mutect2, varscan2
- ACTR3B | c.441G>T p.L147= | Silent (SNP) | VAF 33/281 reads (12%) | called by muse, mutect2, varscan2
- ADNP | c.2157C>T p.Y719= | Silent (SNP) | VAF 175/379 reads (46%) | catalogued as rs587777526, CM144177, COSV104421310; called by muse, mutect2, varscan2
- AGAP5 | c.669C>T p.S223= | Silent (SNP) | VAF 181/492 reads (37%) | called by muse, mutect2, varscan2
- ALG9 | c.72G>A p.A24= | Silent (SNP) | VAF 69/562 reads (12%) | catalogued as rs1555158899; called by muse, mutect2, varscan2
- ANK3 | c.7917G>T p.L2639= | Silent (SNP) | VAF 289/580 reads (50%) | called by muse, mutect2, varscan2
- ARID1B | c.4032G>T p.P1344= | Silent (SNP) | VAF 262/585 reads (45%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.474G>A p.T158= | Silent (SNP) | VAF 138/300 reads (46%) | catalogued as rs200145351; called by muse, varscan2
- BCOR | c.3798C>T p.G1266= (on ENST00000378444 / NM_001123385.2; = p.G1232= on NM_017745.6) | Silent (SNP) | VAF 233/517 reads (45%) | called by muse, mutect2, varscan2
- BTNL2 | c.873G>T p.V291= | Silent (SNP) | VAF 236/459 reads (51%) | called by muse, mutect2, varscan2
- CNGA2 | c.1603C>A p.R535= | Silent (SNP) | VAF 352/721 reads (49%) | catalogued as COSV61703983; called by muse, varscan2
- DNAH17 | c.2985G>A p.T995= | Silent (SNP) | VAF 246/498 reads (49%) | catalogued as rs766742220; called by muse, mutect2, varscan2
- FAM214A | c.303C>T p.S101= | Silent (SNP) | VAF 217/413 reads (53%) | catalogued as rs748189133, COSV55925334; called by muse, mutect2, varscan2
- FBXL19 | c.1104G>A p.G368= | Silent (SNP) | VAF 575/1121 reads (51%) | called by muse, mutect2, varscan2
- FGF23 | c.696G>A p.V232= | Silent (SNP) | VAF 788/1156 reads (68%) | catalogued as COSV52975334; called by muse, mutect2, varscan2
- FTSJ3 | c.321G>A p.K107= | Silent (SNP) | VAF 123/240 reads (51%) | called by muse, mutect2, varscan2
- GPR88 | c.565C>A p.R189= | Silent (SNP) | VAF 390/806 reads (48%) | catalogued as rs78413351; called by muse, mutect2, varscan2
- GRK7 | c.543C>T p.F181= | Silent (SNP) | VAF 278/535 reads (52%) | catalogued as rs141991963, COSV53821732; called by muse, mutect2, varscan2
- KCNQ2 | c.792C>T p.Y264= | Silent (SNP) | VAF 237/515 reads (46%) | catalogued as rs143399744; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNS2 | c.30G>A p.S10= | Silent (SNP) | VAF 212/402 reads (53%) | catalogued as rs184683445, COSV54639926; called by muse, mutect2, varscan2
- KLHL26 | c.585C>T p.I195= | Silent (SNP) | VAF 392/781 reads (50%) | catalogued as rs150325569; called by muse, mutect2, varscan2
- LPCAT2 | c.1152C>T p.F384= | Silent (SNP) | VAF 175/379 reads (46%) | catalogued as rs550820236, COSV50899462; called by muse, mutect2, varscan2
- MCM5 | c.51C>T p.G17= | Silent (SNP) | VAF 258/529 reads (49%) | called by muse, mutect2, varscan2
- MGAM2 | c.4788G>A p.T1596= | Silent (SNP) | VAF 138/320 reads (43%) | catalogued as rs1243323293; called by muse, mutect2, varscan2
- MUC4 | c.5532C>T p.T1844= | Silent (SNP) | VAF 280/1218 reads (23%) | catalogued as rs1222878325; called by muse, varscan2
- MYD88 | c.147G>T p.A49= | Silent (SNP) | VAF 342/685 reads (50%) | called by muse, mutect2, varscan2
- NCOR2 | c.1674C>T p.N558= | Silent (SNP) | VAF 194/419 reads (46%) | catalogued as rs542671777, COSV62298693; called by muse, mutect2, varscan2
- NKX2-3 | c.534C>T p.R178= | Silent (SNP) | VAF 66/895 reads (7%) | called by muse, mutect2
- OGFRL1 | c.1020T>G p.T340= | Silent (SNP) | VAF 219/430 reads (51%) | catalogued as COSV64971630, COSV64972030; called by muse, mutect2, varscan2
- OR11A1 | c.318C>T p.G106= | Silent (SNP) | VAF 436/884 reads (49%) | called by muse, mutect2, varscan2
- OR51B5 | c.117C>A p.G39= | Silent (SNP) | VAF 235/454 reads (52%) | called by muse, mutect2, varscan2
- PLIN2 | c.486A>G p.T162= | Silent (SNP) | VAF 615/618 reads (100%) | catalogued as rs1381263616; called by muse, mutect2, varscan2
- PLIN4 | c.1263C>T p.T421= (on ENST00000301286; = p.T436= on NM_001367868.2) | Silent (SNP) | VAF 291/617 reads (47%) | catalogued as rs372479457; called by muse, mutect2, varscan2
- POLE | c.3990G>A p.P1330= | Silent (SNP) | VAF 270/541 reads (50%) | catalogued as rs777546371; called by muse, mutect2, varscan2
- POLRMT | c.2718C>T p.R906= | Silent (SNP) | VAF 62/817 reads (8%) | catalogued as rs749755810, COSV52117801; called by muse, mutect2
- PRKAR2A | c.549T>G p.T183= | Silent (SNP) | VAF 148/297 reads (50%) | called by muse, mutect2, varscan2
- SCN7A | c.2121T>G p.P707= | Silent (SNP) | VAF 249/507 reads (49%) | catalogued as COSV69270879; called by muse, mutect2, varscan2
- SIGLEC1 | c.1884C>T p.S628= | Silent (SNP) | VAF 389/764 reads (51%) | catalogued as rs1472632783, COSV52466825; called by muse, mutect2, varscan2
- SLC25A10 | c.735G>A p.A245= | Silent (SNP) | VAF 278/559 reads (50%) | catalogued as rs770024783, COSV58971856; called by muse, mutect2, varscan2
- SLITRK5 | c.1764C>T p.D588= | Silent (SNP) | VAF 263/525 reads (50%) | catalogued as COSV61523585; called by muse, mutect2, varscan2
- SPPL2B | c.1063C>T p.L355= | Silent (SNP) | VAF 256/562 reads (46%) | catalogued as rs1268303807; called by muse, mutect2
- SSR3 | c.348G>A p.E116= | Silent (SNP) | VAF 179/374 reads (48%) | called by muse, mutect2, varscan2
- TRIM2 | c.138C>T p.C46= (on ENST00000437508; = p.C73= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 172/324 reads (53%) | called by muse, mutect2, varscan2
- TRMT10A | c.897A>G p.E299= | Silent (SNP) | VAF 285/591 reads (48%) | called by muse, mutect2, varscan2
- TSHZ3 | c.723C>T p.D241= | Silent (SNP) | VAF 508/817 reads (62%) | catalogued as rs772707105, COSV99550423; called by muse, mutect2, varscan2
- VPS13B | c.5898G>T p.L1966= | Silent (SNP) | VAF 201/393 reads (51%) | catalogued as COSV62147887; called by muse, mutect2, varscan2
- WDR90 | c.2715G>A p.S905= | Silent (SNP) | VAF 302/656 reads (46%) | catalogued as rs376123449; called by muse, mutect2
- WNT10B | c.1125G>T p.L375= | Silent (SNP) | VAF 274/538 reads (51%) | catalogued as COSV99975910; called by muse, mutect2, varscan2
- YKT6 | c.111G>A p.Q37= | Silent (SNP) | VAF 151/345 reads (44%) | called by muse, mutect2, varscan2
- YOD1 | c.135G>T p.T45= | Silent (SNP) | VAF 301/597 reads (50%) | called by muse, mutect2, varscan2
- ZNF471 | c.1174C>T p.L392= | Silent (SNP) | VAF 485/744 reads (65%) | called by muse, mutect2, varscan2
- ZNF880 | c.1104C>T p.T368= | Silent (SNP) | VAF 523/739 reads (71%) | catalogued as COSV69906085; called by muse, mutect2, varscan2
- ASCC1 | c.*105G>A | 3'UTR (SNP) | VAF 120/261 reads (46%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2787T>G | Intron (SNP) | VAF 219/739 reads (30%) | called by muse, mutect2, varscan2
- SPIN3 | c.*1686C>T | 3'UTR (SNP) | VAF 165/360 reads (46%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1282+113G>T | Intron (SNP) | VAF 240/500 reads (48%) | called by mutect2, varscan2
